Somatic mutation profile of tumor specimen ALCH-B0FD-TTP1-A (aliquot ALCH-B0FD-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0FD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.2 years (19,787 days).
Specimen ALCH-B0FD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94d6917e-864a-4883-a796-f1af5e32074a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0FD-NB1-A (Blood Derived Normal), aliquot ALCH-B0FD-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e275d72-0417-425d-953a-207d3b68ba2e

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 2, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAP2 | c.1066A>G p.I356V | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.076); catalogued as rs1367685654; called by muse, mutect2, varscan2
- MRPL1 | c.106A>T p.I36F | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV59674557; called by muse, mutect2, varscan2
- OR1N2 | c.871T>C p.F291L | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1205340304; called by muse, mutect2, varscan2
- SP1 | c.923C>T p.A308V (on ENST00000327443 / NM_138473.3; = p.A301V on NM_003109.1) | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs781331460; called by muse, mutect2
- ADAMTS19 | c.1180T>C p.Y394H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADSS2 | c.1081dup p.T361Nfs*23 | Frame Shift Ins (INS) | VAF 19/177 reads (11%) | called by mutect2, pindel, varscan2
- DKKL1 | c.104A>C p.D35A | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- FGD3 | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2
- NPIPA1 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 33/837 reads (4%) | called by muse, mutect2
- PPOX | c.520A>C p.N174H | Missense Mutation (SNP) | VAF 50/415 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- RAB39A | c.320G>C p.W107S | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIPOR1 | c.1835C>G p.P612R (on ENST00000379312 / NM_001193522.2; = p.P608R on NM_024519.4) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- DMXL1 | c.4827G>T p.G1609= | Silent (SNP) | VAF 25/219 reads (11%) | catalogued as COSV60707194; called by muse, mutect2, varscan2
- MROH5 | c.222A>G p.L74= | Silent (SNP) | VAF 14/80 reads (18%) | called by mutect2, varscan2
- OTOP3 | c.933C>T p.T311= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs147650534; called by muse, mutect2, varscan2
- PPP1R8 | c.372C>T p.Y124= | Silent (SNP) | VAF 45/375 reads (12%) | called by muse, mutect2, varscan2
- PRTN3 | c.547C>A p.R183= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-4426G>A | Intron (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- CCDC189 | c.540+12T>C | Intron (SNP) | VAF 18/215 reads (8%) | called by muse, mutect2
- CDC14A | c.-7G>T | 5'UTR (SNP) | VAF 18/124 reads (15%) | catalogued as rs1176220170; called by muse, mutect2, varscan2
- FOXP2 | c.*963T>C | 3'UTR (SNP) | VAF 39/425 reads (9%) | called by muse, mutect2
- POM121 | chr7:72949049 G>A | 3'Flank (SNP) | VAF 16/160 reads (10%) | catalogued as rs141256152; called by muse, mutect2, varscan2
